PECGS case C083-000078 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/5c3ee356-8a7c-45fd-8a95-15180b0856d1

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 25 years; Year of birth: 1998; Education level: College Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 25.0 years (9,131 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000078_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000078_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
